CPTAC case C3L-00356 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b9aedaec-788a-4f8f-8d56-773745b802b9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 1,351 days (3.7 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 73.0 years (26,668 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,351 days (3.7 years); Progression or recurrence: yes; Days to recurrence: 934 days (2.6 years); Days to last follow up: 1,351 days (3.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.9 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 27; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 361 days; Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 713 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,064 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,351 days (3.7 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 934 days (2.6 years).

Other clinical attributes
- Weight: 67 kg; Height: 162.5 cm; BMI: 25.37; Comorbidities: Hyperlipidemia.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00356-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 202 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00356-21: Section location: anterior and posterior; Percent tumor nuclei: 98; Percent necrosis: 2.
- Sample C3L-00356-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 407 mg.
- Sample C3L-00356-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 427 mg.
- Sample C3L-00356-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
